Somatic mutation profile of tumor specimen C3N-02979-01 (aliquot CPT0188100007) from CPTAC case C3N-02979, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.7 years (22,542 days).
Specimen C3N-02979-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d47da6b2-5b07-492d-b120-ec1afd3688cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02979-31 (Blood Derived Normal), aliquot CPT0188120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab095981-8398-497e-ad2b-c824f4d1998b

The open-access MAF lists 1,471 somatic variants for this specimen: 984 protein-altering or splice-affecting, 287 silent, 200 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 660, Silent 287, Frame Shift Del 206, Intron 112, Frame Shift Ins 46, Nonsense Mutation 35, 3'UTR 24, RNA 23, 5'UTR 20, Splice Region 15, 5'Flank 14, Splice Site 12.

Variants (750 of 1,471; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 142/380 reads (37%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 58/193 reads (30%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 445/538 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 195/824 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MC4R | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 175/532 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747681609, CM003760, COSV55351652, COSV55352930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 102/242 reads (42%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 93/317 reads (29%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 93/240 reads (39%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2*
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 490/602 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.983G>A p.R328Q (on ENST00000263121; = p.R374Q on NM_003073.5) | Missense Mutation (SNP) | VAF 189/534 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1057517825, CM1311945, COSV51954334, COSV51955761; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TREM2 | c.482+2T>C p.X161_splice | Splice Site (SNP) | VAF 250/1013 reads (25%) | catalogued as rs386834144, CS022111, COSV58295936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55587378; called by muse, mutect2, varscan2
- ABHD16B | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 164/280 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs761025748; called by muse, mutect2, varscan2
- ACADVL | c.62+3C>T | Splice Region (SNP) | VAF 120/447 reads (27%) | catalogued as rs758445631; called by muse, mutect2, varscan2
- ACOX2 | c.2008A>G p.I670V | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs200020110; called by muse, mutect2, varscan2
- ACSL3 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754373676; called by muse, mutect2, varscan2
- ADAM8 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 128/552 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs1468400617; called by muse, mutect2, varscan2
- ADCY8 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs773033725; called by muse, mutect2, varscan2
- ADD2 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs376703374; called by muse, mutect2, varscan2
- ADGRF2 | c.634G>A p.A212T (on ENST00000296862 / NM_001368115.2; = p.A144T on NM_153839.7) | Missense Mutation (SNP) | VAF 88/388 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777297561, COSV57290921; called by muse, mutect2, varscan2
- AFDN | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 93/375 reads (25%) | catalogued as rs1245165524; called by muse, mutect2, varscan2
- AFDN | c.3764del p.K1255Sfs*38 | Frame Shift Del (DEL) | VAF 88/400 reads (22%) | catalogued as COSV60050381; called by pindel, varscan2
- AHNAK2 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as rs200025024, COSV60917709; called by muse, mutect2, varscan2
- AL096814.1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs927330712; called by muse, mutect2
- ALDH1B1 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756415334, COSV66619656; called by muse, mutect2, varscan2
- ALG2 | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 136/425 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs982166395; called by muse, mutect2, varscan2
- ALG5 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV99523910; called by muse, mutect2, varscan2
- ALS2CL | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143737668; called by muse, mutect2, varscan2
- ANK3 | c.10709C>T p.A3570V | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.17); catalogued as rs762671321, COSV55085165; called by muse, mutect2, varscan2
- ANKAR | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55616256; called by muse, mutect2, varscan2
- ANKRD18A | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs1272392878; called by muse, mutect2, varscan2
- ANKRD24 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 72/528 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as rs927092364; called by muse, mutect2, varscan2
- ANKRD28 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1275383974; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 176/436 reads (40%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- AQR | c.4022C>T p.T1341I | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs999892425; called by muse, mutect2, varscan2
- AREG | c.311-3del | Splice Region (DEL) | VAF 195/592 reads (33%) | catalogued as rs1267456101; called by mutect2, pindel, varscan2
- ARHGAP10 | c.395del p.K132Rfs*13 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as rs1272122079; called by mutect2, pindel, varscan2
- ARHGAP22 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 282/514 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1235060824, COSV99985583; called by muse, mutect2, varscan2
- ARHGAP35 | c.2587C>G p.R863G | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68330957; called by muse, mutect2, varscan2
- ARID1A | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 194/551 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); catalogued as COSV61372201; called by mutect2, varscan2
- ARMC12 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 232/955 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1054782659; called by muse, mutect2, varscan2
- ARMC5 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as rs572218981; called by muse, mutect2, varscan2
- ASB7 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 17/611 reads (3%) | catalogued as COSV58404655; called by muse, mutect2
- ASTN2 | c.3520A>G p.T1174A (on ENST00000313400 / NM_001365069.1; = p.T1123A on NM_014010.5) | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV56001158; called by muse, mutect2, varscan2
- ATP13A1 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 67/299 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327863953; called by muse, mutect2, varscan2
- ATP13A5 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.395); catalogued as COSV100665130; called by muse, mutect2, varscan2
- ATP1B3 | c.139del p.Y47Mfs*42 | Frame Shift Del (DEL) | VAF 124/371 reads (33%) | catalogued as COSV53949154; called by mutect2, pindel, varscan2
- ATP2A3 | c.2447T>C p.I816T | Missense Mutation (SNP) | VAF 242/686 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99989114; called by muse, mutect2, varscan2
- AVPR1B | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs371543948; called by muse, mutect2, varscan2
- BCAS3 | c.46_48del p.C16del | In Frame Del (DEL) | VAF 110/315 reads (35%) | catalogued as rs766607946; called by mutect2, pindel, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 134/233 reads (58%) | catalogued as rs1184020574; called by mutect2, pindel, varscan2
- BIRC6 | c.1874_1876del p.R625del | In Frame Del (DEL) | VAF 83/295 reads (28%) | catalogued as rs770311139; called by pindel, varscan2
- BNIP3L | c.122T>C p.M41T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs776414316; called by muse, mutect2, varscan2
- BRCA2 | c.4049A>G p.H1350R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV66461191; called by muse, mutect2, varscan2
- BSN | c.10771C>G p.R3591G | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs373022358; called by muse, mutect2, varscan2
- C1orf198 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs758657914; called by muse, mutect2, varscan2
- C4BPB | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1400432189, COSV99700201; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 178/555 reads (32%) | catalogued as rs372345940; called by mutect2, varscan2
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | catalogued as rs951061763; called by mutect2, varscan2
- CACNA1E | c.2562del p.S855Pfs*52 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs753503928; called by mutect2, pindel, varscan2
- CACNB1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 121/347 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757223702, COSV100703321; called by muse, mutect2, varscan2
- CACTIN | c.1694C>G p.T565R | Missense Mutation (SNP) | VAF 203/738 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV50272325; called by muse, mutect2, varscan2
- CAMK4 | c.1403T>C p.V468A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV56673341; called by mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 84/252 reads (33%) | catalogued as rs770273913; called by mutect2, varscan2
- CASR | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 144/367 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.078); catalogued as CM962440; called by muse, mutect2, varscan2
- CCDC120 | c.1881dup p.C628Vfs*23 | Frame Shift Ins (INS) | VAF 97/314 reads (31%) | catalogued as rs1256077331; called by mutect2, pindel, varscan2
- CCDC166 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 227/598 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as rs1554616986; called by muse, mutect2, varscan2
- CCDC175 | c.1895del p.N632Tfs*8 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCDC85C | c.1014del p.S339Lfs*18 | Frame Shift Del (DEL) | VAF 80/314 reads (25%) | catalogued as rs1336006653; called by mutect2, pindel
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 296/475 reads (62%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 114/477 reads (24%) | catalogued as rs1276928429, COSV55666935; called by mutect2, varscan2
- CDHR5 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746933488; called by muse, mutect2, varscan2
- CELSR3 | c.5645C>T p.A1882V | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs878928399, COSV99374486; called by muse, mutect2, varscan2
- CEP104 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764293694; called by muse, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 69/252 reads (27%) | catalogued as rs763364101; called by mutect2, varscan2
- CHD1 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99400186; called by muse, mutect2, varscan2
- CHD7 | c.2758C>T p.R920W | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs773773546; called by muse, mutect2, varscan2
- CHI3L1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1451589736; called by muse, mutect2, varscan2
- CHPF | c.1423del p.Q475Rfs*17 | Frame Shift Del (DEL) | VAF 279/490 reads (57%) | catalogued as COSV99705158; called by mutect2, pindel, varscan2
- CIT | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1459319568; called by muse, mutect2, varscan2
- CLDN34 | c.140del p.P47Lfs*48 | Frame Shift Del (DEL) | VAF 154/441 reads (35%) | catalogued as rs916875657; called by mutect2, pindel, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | catalogued as rs758676375; called by mutect2, varscan2
- COBL | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs531529738, COSV54337941; called by muse, mutect2, varscan2
- COL11A1 | c.2960C>A p.P987H | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1414541088; called by muse, mutect2, varscan2
- COL12A1 | c.4590G>A p.M1530I | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1328141615; called by muse, mutect2, varscan2
- COL18A1 | c.3356G>C p.G1119A (on ENST00000359759 / NM_130444.3; = p.G884A on NM_030582.4) | Missense Mutation (SNP) | VAF 222/711 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100645413; called by mutect2, varscan2
- COL1A1 | c.4039G>A p.D1347N | Missense Mutation (SNP) | VAF 171/439 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs191166865; called by muse, mutect2, varscan2
- COL1A2 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 235/860 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1211690, COSV51960242; called by muse, mutect2, varscan2
- COL22A1 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV57328487; called by muse, mutect2, varscan2
- COMMD10 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215479730, COSV57233826; called by muse, mutect2, varscan2
- CORO7 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs538497679; called by muse, mutect2, varscan2
- CRACDL | c.1131del p.A378Qfs*121 | Frame Shift Del (DEL) | VAF 73/241 reads (30%) | catalogued as rs767494728, COSV67408370; called by mutect2, pindel, varscan2
- CRACR2B | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as rs1388794776; called by muse, mutect2, varscan2
- CRNKL1 | c.2358_2361del p.K787Sfs*76 | Frame Shift Del (DEL) | VAF 86/267 reads (32%) | catalogued as rs1305159004; called by mutect2, pindel, varscan2
- CSF3 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs769990271, COSV56641636; called by muse, mutect2
- CTH | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551720451, CM099466; called by muse, mutect2, varscan2
- CUL9 | c.5888A>G p.Q1963R | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.702); catalogued as rs751682495; called by muse, mutect2, varscan2
- CYP2F1 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.061); catalogued as COSV100462803; called by muse, varscan2
- CYP2J2 | c.1132del p.L378* | Frame Shift Del (DEL) | VAF 110/349 reads (32%) | catalogued as rs1559073681; called by mutect2, pindel, varscan2
- DCAF10 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs757840615; called by muse, mutect2, varscan2
- DDX39B | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV100795313; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | catalogued as rs773554787; called by mutect2, pindel
- DDX60L | c.994del p.M332* | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | catalogued as COSV52711802; called by mutect2, pindel, varscan2
- DGCR2 | c.1613del p.G538Vfs*111 | Frame Shift Del (DEL) | VAF 113/452 reads (25%) | catalogued as rs1278157389; called by mutect2, pindel, varscan2
- DGCR2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs1384675843; called by muse, mutect2, varscan2
- DGKG | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs748682125; called by muse, varscan2
- DHRSX | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 152/488 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs754803328, COSV58139598; called by muse, mutect2, varscan2
- DIPK1B | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 101/362 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1307766568; called by muse, mutect2, varscan2
- DLL1 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 463/849 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754128922; called by muse, mutect2, varscan2
- DNAH1 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 211/576 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs200623391, COSV70227029; called by muse, mutect2, varscan2
- DNAH11 | c.6988G>A p.V2330M | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766617896, COSV60937599; called by muse, mutect2, varscan2
- DNAH3 | c.6541G>A p.V2181M | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs767378232, COSV99770847; called by muse, mutect2, varscan2
- DOCK1 | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 112/452 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54755382; called by muse, mutect2, varscan2
- DOCK7 | c.3584C>T p.A1195V (on ENST00000635253 / NM_001367561.1; = p.A1164V on NM_033407.3) | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs1199336037; called by muse, mutect2, varscan2
- DPP6 | c.551T>C p.I184T (on ENST00000377770 / NM_001364500.2; = p.I122T on NM_001936.5) | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV59654319; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 188/543 reads (35%) | catalogued as rs1475611014; called by mutect2, varscan2
- DRAM2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs145044841, COSV54415436; called by muse, mutect2, varscan2
- DRG2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 229/562 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs755187661, COSV99854998; called by muse, mutect2, varscan2
- DST | c.4997T>C p.L1666P | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55041493; called by muse, mutect2, varscan2
- DUSP23 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 120/398 reads (30%) | catalogued as rs763731199, COSV63659940; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 148/389 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs373451243; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EGR3 | c.1128dup p.V377Rfs*30 | Frame Shift Ins (INS) | VAF 46/138 reads (33%) | catalogued as rs749768945; called by mutect2, pindel, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 120/291 reads (41%) | catalogued as rs766700925; called by mutect2, varscan2
- EML6 | c.2051+1del | Frame Shift Del (DEL) | VAF 56/172 reads (33%) | catalogued as COSV100728292; called by mutect2, pindel, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 84/182 reads (46%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- ENOX1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs748848402; called by muse, mutect2, varscan2
- EPAS1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 156/485 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55383997; called by muse, mutect2, varscan2
- EPC1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 287/555 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs143130252; called by muse, mutect2, varscan2
- EPHA8 | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 222/588 reads (38%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.821); catalogued as rs146237497; called by muse, varscan2
- EPS15 | c.1917C>T p.I639= | Splice Region (SNP) | VAF 26/90 reads (29%) | catalogued as rs148068749; called by muse, mutect2, varscan2
- EPSTI1 | c.797G>A p.R266Q (on ENST00000398762 / NM_001330543.2; = p.R255Q on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/368 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as rs753018513, COSV58048131; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 223/933 reads (24%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ETV3 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs183796584; called by muse, mutect2, varscan2
- EXOG | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371616022, COSV55063243; called by muse, mutect2, varscan2
- F2RL3 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 377/1362 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.143); catalogued as rs756275699; called by muse, mutect2, varscan2
- FABP12 | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 139/414 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64617425, COSV64617928; called by muse, mutect2, varscan2
- FAM193B | c.219del p.A74Pfs*49 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | catalogued as rs765995572, COSV61557636; called by mutect2, pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 62/134 reads (46%) | catalogued as rs746881923; called by mutect2, varscan2
- FAM47B | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.073); catalogued as COSV61457262; called by muse, mutect2, varscan2
- FAM83E | c.1305del p.A436Pfs*105 | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | catalogued as COSV99572212; called by mutect2, pindel, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 136/177 reads (77%) | catalogued as rs757443519; called by mutect2, varscan2
- FAT4 | c.5533G>A p.V1845M | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs1179341769, COSV58691310, COSV58700791; called by muse, mutect2, varscan2
- FGL2 | c.189del p.L64* | Frame Shift Del (DEL) | VAF 130/594 reads (22%) | catalogued as rs748863945, COSV50381627; called by mutect2, pindel, varscan2
- FHAD1 | c.2857del p.I953* | Frame Shift Del (DEL) | VAF 139/483 reads (29%) | catalogued as rs769346962; called by mutect2, pindel, varscan2
- FIGNL1 | c.48_50del p.K16del | In Frame Del (DEL) | VAF 32/144 reads (22%) | catalogued as rs749507967; called by pindel, varscan2
- FIZ1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 205/818 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55607119; called by muse, mutect2, varscan2
- FLNA | c.3514C>T p.R1172W | Missense Mutation (SNP) | VAF 126/486 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1557177743, COSV61046139; called by muse, mutect2, varscan2
- FLOT2 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 123/320 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67528995; called by muse, mutect2, varscan2
- FOXJ1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 118/304 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs1385574006; called by muse, mutect2, varscan2
- FRMPD2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 187/669 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs373231008; called by muse, mutect2, varscan2
- FZD1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 165/565 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99078396; called by muse, mutect2, varscan2
- GATA2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 149/361 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs767059760; called by muse, mutect2, varscan2
- GCAT | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 135/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772912290; called by muse, mutect2, varscan2
- GFRA4 | c.560C>T p.A187V (on ENST00000319242 / NM_145762.3; = p.R161C on NM_022139.4) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as rs1413214377; called by muse, mutect2, varscan2
- GHRHR | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 176/750 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs867798003; called by muse, mutect2, varscan2
- GIMAP8 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 112/406 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758660235, COSV56232362; called by muse, mutect2, varscan2
- GJB6 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 142/411 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs754202125, COSV53831714; called by muse, mutect2, varscan2
- GLI1 | c.821dup p.C275Lfs*32 | Frame Shift Ins (INS) | VAF 114/244 reads (47%) | catalogued as rs759448855; called by mutect2, varscan2
- GLP1R | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.537); catalogued as rs148158586; called by muse, mutect2, varscan2
- GOLGA4 | c.6520G>A p.E2174K | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750023676, COSV62710105; called by muse, mutect2, varscan2
- GP5 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 122/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99755950; called by muse, mutect2, varscan2
- GP6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 557/1048 reads (53%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs767901432, COSV59976378; called by muse, mutect2, varscan2
- GPN2 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1334865513; called by muse, mutect2, varscan2
- GPR179 | c.6790C>T p.R2264W (on ENST00000621958; = p.R2263W on NM_001004334.4) | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs369317806; called by muse, mutect2, varscan2
- GPR35 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 302/780 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs377190882, COSV100166477, COSV100166776; called by muse, mutect2, varscan2
- GPR45 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 235/617 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99306912; called by muse, mutect2, varscan2
- GPRC5C | c.695G>A p.G232D (on ENST00000652232; = p.G187D on NM_018653.4) | Missense Mutation (SNP) | VAF 216/600 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs369264703; called by muse, mutect2, varscan2
- GREB1L | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs760577439, COSV99337269; called by muse, mutect2, varscan2
- GRK7 | c.1190del p.K397Rfs*7 | Frame Shift Del (DEL) | VAF 61/296 reads (21%) | catalogued as rs775724780; called by mutect2, pindel, varscan2
- GRM5 | c.2552A>G p.K851R | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV59617648; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 246/1111 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs782262891; called by muse, mutect2, varscan2
- GZMK | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 129/407 reads (32%) | catalogued as rs372763068; called by muse, mutect2, varscan2
- H1-1 | c.513dup p.P172Tfs*11 | Frame Shift Ins (INS) | VAF 134/556 reads (24%) | catalogued as rs749012967; called by mutect2, varscan2
- HCN3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 263/714 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771587960, COSV104428179; called by muse, mutect2, varscan2
- HDAC9 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 101/433 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV67766183; called by muse, mutect2, varscan2
- HECTD2 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as rs373060101; called by muse, mutect2, varscan2
- HERC1 | c.3643C>T p.R1215W | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs748836788, COSV71245849; called by muse, mutect2, varscan2
- HGFAC | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs773163201; called by muse, mutect2, varscan2
- HGS | c.37+7C>T | Splice Region (SNP) | VAF 58/245 reads (24%) | catalogued as rs1181672539; called by muse, mutect2, varscan2
- HGSNAT | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs374287774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HLA-A | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 134/686 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772821446, COSV100954632; called by muse, mutect2, varscan2
- HLA-DQB2 | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 123/425 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs764317349; called by muse, mutect2, varscan2
- HSDL1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1555517035; called by muse, mutect2, varscan2
- HTR3E | c.919del p.L307Sfs*12 (on ENST00000415389 / NM_001256613.1; = p.L322Sfs*12 on NM_182589.2) | Frame Shift Del (DEL) | VAF 115/347 reads (33%) | catalogued as rs754509192; called by mutect2, pindel, varscan2
- HTR6 | c.1120del p.L374Cfs*80 | Frame Shift Del (DEL) | VAF 246/756 reads (33%) | catalogued as COSV99230567; called by mutect2, pindel, varscan2
- IDI1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67281375; called by muse, mutect2, varscan2
- IGFALS | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM102504; called by muse, mutect2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 133/424 reads (31%) | catalogued as rs778799414; called by mutect2, pindel, varscan2
- IGSF9B | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs772351117; called by muse, varscan2
- IK | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436446769; called by muse, mutect2, varscan2
- ILVBL | c.336C>T p.S112= | Splice Region (SNP) | VAF 72/213 reads (34%) | catalogued as rs765311341, COSV54619049; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTU | c.395del p.N132Ifs*11 | Frame Shift Del (DEL) | VAF 74/158 reads (47%) | catalogued as rs771175764; called by mutect2, varscan2
- IRAG1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs373371120, COSV101351693; called by muse, mutect2
- IRGC | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 170/752 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs771051245, COSV54985541; called by muse, mutect2, varscan2
- ITPRIP | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781468796; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 36/131 reads (27%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JMJD6 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs767092762; called by muse, mutect2, varscan2
- KCNAB2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV51239248; called by muse, mutect2, varscan2
- KCNH8 | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV60471126; called by muse, mutect2, varscan2
- KCP | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs73461538; called by muse, mutect2, varscan2
- KCTD16 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 212/512 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as rs766543181, COSV72580779; called by muse, mutect2, varscan2
- KIAA1614 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs377327095; called by muse, mutect2, varscan2
- KIF15 | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1452351659; called by muse, mutect2, varscan2
- KLHL29 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as rs1477760310, COSV101517097; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 25/185 reads (14%) | catalogued as rs749194179; called by mutect2, pindel
- KLK11 | c.779G>A p.R260Q (on ENST00000594768 / NM_144947.3; = p.R228Q on NM_006853.3) | Missense Mutation (SNP) | VAF 168/1115 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs200362022, COSV59397598; called by muse, mutect2, varscan2
- KRT12 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200941376, COSV52430559; called by muse, mutect2, varscan2
- LAMA2 | c.7424C>T p.T2475M | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs761500524, COSV70353446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA3 | c.2083A>G p.M695V | Missense Mutation (SNP) | VAF 275/694 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100556061; called by muse, mutect2, varscan2
- LAP3 | c.896T>C p.M299T | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159016084; called by muse, mutect2, varscan2
- LARP1 | c.1019G>A p.R340H (on ENST00000518297 / NM_033551.3; = p.R263H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs759446230; called by muse, mutect2, varscan2
- LDHC | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs201168555, COSV55004333; called by muse, mutect2, varscan2
- LHX3 | c.314G>A p.R105H (on ENST00000371748 / NM_178138.6; = p.R110H on NM_014564.5) | Missense Mutation (SNP) | VAF 223/536 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs917604349, COSV65581413; called by muse, mutect2, varscan2
- LMO7 | c.1069A>G p.T357A (on ENST00000357063; = p.T87A on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs765469255; called by muse, mutect2, varscan2
- LMTK3 | c.2175del p.A726Pfs*132 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1555901301; called by mutect2, varscan2
- LOXL4 | c.403del p.R135Gfs*40 | Frame Shift Del (DEL) | VAF 141/324 reads (44%) | catalogued as COSV53257058, COSV99583837; called by mutect2, pindel, varscan2
- LRP1 | c.11429G>A p.R3810H | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs1351361070; called by muse, mutect2, varscan2
- LRRTM3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as COSV100791510; called by muse, mutect2, varscan2
- LURAP1L | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 238/654 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs755731741; called by muse, mutect2, varscan2
- MAD2L1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as rs1293894024; called by muse, mutect2
- MAP1A | c.5104T>C p.C1702R | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as rs941124743; called by muse, mutect2, varscan2
- MAP3K1 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.566); catalogued as rs530669321, COSV68123137; called by muse, mutect2, varscan2
- MAP3K21 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs751751975; called by muse, mutect2, varscan2
- MAP3K5 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs760771515; called by muse, mutect2, varscan2
- MAPK12 | c.427-5del | Splice Region (DEL) | VAF 65/184 reads (35%) | catalogued as rs752922316; called by mutect2, pindel, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 65/262 reads (25%) | catalogued as rs770972906; called by mutect2, varscan2
- MAST2 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 154/463 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs753209432, COSV63618826; called by muse, mutect2, varscan2
- MAU2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.403); catalogued as rs369228779, COSV99448965; called by muse, mutect2, varscan2
- MCOLN1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 207/1287 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as rs372323549; called by muse, mutect2, varscan2
- MDN1 | c.11812dup p.L3938Pfs*6 | Frame Shift Ins (INS) | VAF 31/134 reads (23%) | catalogued as rs764349848; called by mutect2, pindel, varscan2
- ME3 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs763016370, COSV100042010; called by muse, mutect2, varscan2
- MED13 | c.1256C>T p.T419I | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); catalogued as rs1223784826; called by muse, mutect2, varscan2
- MED16 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 102/418 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751604368; called by muse, mutect2, varscan2
- MED30 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs144333065; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 87/285 reads (31%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- METTL22 | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV50838254; called by muse, mutect2, varscan2
- MFSD14A | c.806dup p.L269Ffs*43 | Frame Shift Ins (INS) | VAF 64/242 reads (26%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 168/318 reads (53%) | catalogued as rs746398787; called by mutect2, varscan2
- MMRN1 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV99306817; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 78/282 reads (28%) | catalogued as rs755830405; called by mutect2, varscan2
- MRPL10 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs1164999596; called by muse, mutect2, varscan2
- MRPL2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 165/311 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as rs751522499, COSV99431726; called by muse, mutect2, varscan2
- MRPL47 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 66/198 reads (33%) | catalogued as rs754188894; called by muse, mutect2, varscan2
- MTCL1 | c.2152G>A p.E718K (on ENST00000306329 / NM_001378206.1; = p.E358K on NM_015210.4) | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs766057158; called by muse, mutect2, varscan2
- MTR | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 224/585 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs751565093; called by muse, mutect2, varscan2
- MUC12 | c.988C>A p.P330T (on ENST00000379442; = p.P187T on NM_001164462.1) | Missense Mutation (SNP) | VAF 186/762 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs199521685; called by muse, mutect2, varscan2
- MUC16 | c.17711C>T p.T5904I | Missense Mutation (SNP) | VAF 123/494 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as rs766376019; called by muse, mutect2, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 164/198 reads (83%) | catalogued as rs537060918; called by mutect2, varscan2
- MYB | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.23); catalogued as rs755251168; called by muse, mutect2, varscan2
- MYH14 | c.5599C>T p.R1867W | Missense Mutation (SNP) | VAF 220/433 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1272434745, COSV51813320; called by muse, mutect2, varscan2
- MYO1C | c.2401dup p.R801Pfs*42 (on ENST00000648651 / NM_001080779.2; = p.R766Pfs*42 on NM_033375.5) | Frame Shift Ins (INS) | VAF 47/158 reads (30%) | catalogued as rs1446133378; called by mutect2, pindel, varscan2
- MYO3B | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 515/691 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763702794; called by muse, mutect2, varscan2
- MYO5C | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 135/538 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1293591383, COSV99955864; called by muse, mutect2, varscan2
- MYOD1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs778253720; called by muse, mutect2, varscan2
- MYT1L | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 117/459 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867648634, COSV101220821, COSV67719126; called by muse, mutect2, varscan2
- NADK | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 175/434 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.159); catalogued as rs1325065325; called by muse, mutect2, varscan2
- NAPRT | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867606090; called by muse, mutect2, varscan2
- NAT8L | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1179686445; called by muse, mutect2, varscan2
- NCAM1 | c.1189G>A p.A397T (on ENST00000316851 / NM_181351.5; = p.A387T on NM_000615.7) | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781876684, COSV57518403; called by muse, mutect2, varscan2
- NCKAP5L | c.2603C>T p.T868I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1000918310; called by muse, mutect2, varscan2
- NCOA7 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs1289779619; called by muse, mutect2, varscan2
- NECTIN1 | c.1219del p.Q407Sfs*191 | Frame Shift Del (DEL) | VAF 222/756 reads (29%) | catalogued as COSV50605488; called by pindel, varscan2
- NEFH | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 222/614 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60217055; called by muse, mutect2, varscan2
- NF2 | c.576C>G p.Y192* | Nonsense Mutation (SNP) | VAF 185/476 reads (39%) | catalogued as CM994608, COSV100097796, COSV58520186, COSV58532890; called by muse, varscan2
- NIPBL | c.8390C>T p.A2797V | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs865937237, COSV56957136; called by muse, mutect2, varscan2
- NISCH | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 249/688 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs761618364, COSV61898413; called by muse, mutect2, varscan2
- NKD2 | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.775); catalogued as COSV56890110; called by muse, mutect2, varscan2
- NMB | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs746299945, COSV64685606; called by muse, mutect2, varscan2
- NME9 | c.755G>A p.R252H (on ENST00000333911 / NM_001349024.2; = p.R191H on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.493); catalogued as rs953747696; called by muse, mutect2, varscan2
- NOD1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | catalogued as rs371807148; called by muse, mutect2, varscan2
- NOP53 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 269/505 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as rs11538670, COSV55882727; called by muse, mutect2, varscan2
- NPAP1 | c.3232G>A p.V1078I | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs1288533660; called by muse, mutect2, varscan2
- NPAS3 | c.400C>T p.R134* (on ENST00000356141 / NM_001164749.2; = p.R102* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 104/280 reads (37%) | catalogued as COSV58078141; called by muse, varscan2
- NPR1 | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs138609379; called by muse, mutect2, varscan2
- NR1I3 | c.1006C>T p.H336Y (on ENST00000367982 / NM_001077480.3; = p.H332Y on NM_005122.5) | Missense Mutation (SNP) | VAF 153/488 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs373882046, COSV100915667; called by muse, mutect2, varscan2
- NRG3 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs372414340; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 134/270 reads (50%) | catalogued as COSV55073962; called by mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 85/267 reads (32%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 65/208 reads (31%) | catalogued as rs777887578; called by mutect2, varscan2
- OLFML2B | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs767755142; called by muse, mutect2, varscan2
- OPRM1 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100001215; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 129/662 reads (19%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR12D2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1169993686, COSV65826795; called by muse, mutect2, varscan2
- OR14C36 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV58601560, COSV58602691; called by muse, mutect2, varscan2
- OR2B2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs781638205, COSV57579810, COSV57580640; called by muse, mutect2, varscan2
- OR2K2 | c.125del p.F42Sfs*11 (on ENST00000374428; = p.F13Sfs*11 on NM_205859.2) | Frame Shift Del (DEL) | VAF 72/234 reads (31%) | catalogued as rs751046224; called by mutect2, pindel, varscan2
- OR5J2 | c.933_934del p.C312Lfs*? | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs765314988; called by pindel, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 120/531 reads (23%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 64/248 reads (26%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- OSBPL10 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 204/517 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.363); catalogued as rs1010053434, COSV67343483; called by muse, mutect2, varscan2
- OSBPL10 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1414016463; called by muse, mutect2, varscan2
- OSBPL6 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); catalogued as rs746370588; called by muse, mutect2, varscan2
- OTOGL | c.1076G>A p.C359Y (on ENST00000547103; = p.C350Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299012895; called by muse, mutect2, varscan2
- OTUD3 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs773217184; called by muse, mutect2, varscan2
- OVOL3 | c.464G>A p.C155Y (on ENST00000585332; = p.C131Y on NM_001302757.1) | Missense Mutation (SNP) | VAF 147/539 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764258836; called by muse, mutect2, varscan2
- P2RY12 | c.899dup p.L301Pfs*27 | Frame Shift Ins (INS) | VAF 50/214 reads (23%) | catalogued as rs779678942; called by mutect2, pindel, varscan2
- PARP9 | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 58/145 reads (40%) | catalogued as COSV64449861; called by muse, mutect2, varscan2
- PCDHA3 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 248/755 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63542084; called by muse, mutect2, varscan2
- PCDHA5 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 198/609 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1467211274, COSV65357727; called by muse, mutect2, varscan2
- PCDHB15 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 366/1009 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV51424178; called by mutect2, varscan2
- PCDHGA8 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 136/250 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV53997627; called by muse, mutect2, varscan2
- PCDHGB2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 316/753 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV53960203; called by muse, mutect2, varscan2
- PCDHGB2 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.022); catalogued as rs761668802, COSV54046285; called by muse, mutect2, varscan2
- PDE9A | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748749285, COSV52332989; called by muse, mutect2, varscan2
- PDZD2 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 155/418 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs776212299; called by muse, mutect2, varscan2
- PEG3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 196/438 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1046467329, COSV55638306; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 40/151 reads (26%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2
- PHF14 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 81/294 reads (28%) | catalogued as rs760800245, COSV68857032; called by muse, mutect2, varscan2
- PI4KA | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 155/493 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1189930663, COSV55424886; called by muse, mutect2, varscan2
- PIEZO2 | c.7024C>T p.P2342S | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53288673; called by muse, mutect2, varscan2
- PIGZ | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.041); catalogued as rs754667053, COSV99434012; called by muse, mutect2, varscan2
- PIP5K1B | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs2297232; called by muse, mutect2, varscan2
- PKDREJ | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1277764626; called by muse, mutect2, varscan2
- PKMYT1 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51892519; called by muse, mutect2, varscan2
- PKP4 | c.3538A>G p.R1180G | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474109867; called by muse, mutect2
- PLEKHG4B | c.2704C>T p.P902S (on ENST00000283426; = p.P1258S on NM_052909.5) | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs1176489832; called by muse, mutect2, varscan2
- PLEKHG7 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 194/246 reads (79%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.652); catalogued as rs146227771; called by muse, mutect2
- PLXNB2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 233/596 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs766516184, COSV100833880; called by muse, mutect2, varscan2
- POF1B | c.47C>A p.T16N | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs749094973; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 82/372 reads (22%) | catalogued as rs745933237; called by mutect2, varscan2
- POR | c.822C>G p.N274K | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs1348698902; called by muse, mutect2, varscan2
- POTEC | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1297902481; called by muse, mutect2, varscan2
- PPFIA1 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 114/352 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs750191381, COSV54131213; called by muse, mutect2, varscan2
- PPIP5K2 | c.3713del p.N1238Tfs*35 (on ENST00000358359 / NM_001276277.3; = p.N1217Tfs*35 on NM_015216.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/209 reads (21%) | catalogued as rs201392612; called by mutect2, varscan2
- PPL | c.4999C>T p.R1667C | Missense Mutation (SNP) | VAF 150/478 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs532677347; called by muse, mutect2, varscan2
- PPP1R32 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1565138663, COSV58544118; called by muse, mutect2, varscan2
- PPRC1 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 147/511 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs371010227, COSV53386473; called by muse, mutect2, varscan2
- PRAM1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 212/394 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs530402541, COSV55314734; called by muse, mutect2, varscan2
- PRIMPOL | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs773359056, COSV59248118; called by muse, mutect2, varscan2
- PRKD1 | c.1127A>G p.Q376R | Missense Mutation (SNP) | VAF 129/662 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs746144187; called by muse, mutect2, varscan2
- PRRC2B | c.4156C>T p.R1386W | Missense Mutation (SNP) | VAF 125/316 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1345202148; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 88/226 reads (39%) | catalogued as rs781858060; called by mutect2, varscan2
- PRRT4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1395852433, COSV101435696; called by muse, mutect2, varscan2
- PSKH1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 177/483 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs1273563995; called by muse, mutect2, varscan2
- PSMC3 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 144/459 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779894566, COSV54080032; called by muse, mutect2, varscan2
- PTBP1 | c.931del p.L311Wfs*57 (on ENST00000349038 / NM_031991.4; = p.L337Wfs*57 on NM_002819.5) | Frame Shift Del (DEL) | VAF 82/554 reads (15%) | catalogued as rs1421431048; called by mutect2, varscan2
- PVRIG | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs143637820; called by muse, mutect2, varscan2
- PXN | c.144del p.V49Sfs*18 | Frame Shift Del (DEL) | VAF 110/336 reads (33%) | catalogued as rs758654594; called by mutect2, varscan2
- PYGM | c.521del p.G174Afs*121 | Frame Shift Del (DEL) | VAF 252/752 reads (34%) | catalogued as CM071070, COSV99377165; called by mutect2, pindel, varscan2
- QRICH2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 183/503 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs754459255, COSV53152204; called by muse, mutect2, varscan2
- QTRT2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 189/533 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs556151258; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 195/240 reads (81%) | catalogued as COSV100234622; called by mutect2, varscan2
- RABGAP1L | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.155); catalogued as rs766484367; called by muse, mutect2, varscan2
- RABL6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs779589434, COSV61032756; called by muse, mutect2, varscan2
- RAD54L2 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1197843664; called by muse, mutect2
- RALGAPB | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs778173447; called by muse, mutect2, varscan2
- RARRES1 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as rs780550373; called by muse, mutect2, varscan2
- RASA1 | c.1451del p.K484Rfs*14 | Frame Shift Del (DEL) | VAF 71/247 reads (29%) | catalogued as rs34028699; called by mutect2, pindel, varscan2
- RASAL2 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.405); catalogued as rs1451943548, COSV100862982; called by muse, mutect2
- RASL10A | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 203/595 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.56); catalogued as rs915552705; called by muse, mutect2, varscan2
- RBM33 | c.434_436del p.E145del | In Frame Del (DEL) | VAF 106/492 reads (22%) | catalogued as rs760521273; called by pindel, varscan2
- RD3L | c.1del p.M1? | Frame Shift Del (DEL) | VAF 37/107 reads (35%) | catalogued as rs1189167268; called by mutect2, pindel, varscan2
- RECQL4 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as rs915387235, COSV52879503; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 90/210 reads (43%) | catalogued as rs759247453; called by mutect2, varscan2
- RET | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 244/882 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs61843232; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFX3 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 182/506 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV101137613; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | catalogued as rs751982308; called by mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIN3 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV99378864; called by muse, mutect2, varscan2
- RIPK4 | c.1456G>A p.G486S (on ENST00000352483; = p.G438S on NM_020639.3) | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1055788509, COSV60185943; called by muse, mutect2, varscan2
- RND2 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56816640; called by muse, mutect2, varscan2
- RNF133 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1448754269; called by muse, mutect2, varscan2
- RNPEPL1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs765362932; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 56/182 reads (31%) | catalogued as rs745519558; called by mutect2, varscan2
- ROR1 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV64294609; called by muse, mutect2
- RPL28 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 168/288 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV59804626; called by muse, mutect2, varscan2
- RRP15 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs139831875; called by muse, mutect2, varscan2
- RTEL1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 218/442 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs200555432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTKN | c.1598G>A p.R533H (on ENST00000272430 / NM_001015055.2; = p.R520H on NM_033046.2) | Missense Mutation (SNP) | VAF 113/279 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs761287012, COSV51966581; called by muse, mutect2, varscan2
- RUFY2 | c.1603del p.I535Yfs*26 | Frame Shift Del (DEL) | VAF 51/268 reads (19%) | catalogued as rs894118734; called by mutect2, pindel, varscan2
- S1PR1 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs200913242, COSV59513501, COSV59513537; called by muse, mutect2, varscan2
- SAP25 | c.351del p.I118Sfs*26 (on ENST00000538735; = p.I216Sfs*26 on NM_001168682.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs1247552106; called by mutect2, pindel, varscan2
- SATB2 | c.598-4del | Splice Region (DEL) | VAF 60/198 reads (30%) | catalogued as rs199978702; ClinVar: benign / likely benign; called by mutect2, varscan2
- SBNO1 | c.763C>T p.R255C (on ENST00000420886; = p.R254C on NM_018183.5) | Missense Mutation (SNP) | VAF 165/357 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs773791743, COSV57338935; called by muse, mutect2, varscan2
- SDK1 | c.4403T>C p.V1468A | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV101269672; called by mutect2, varscan2
- SDR39U1 | c.124-1G>T p.X42_splice | Splice Site (SNP) | VAF 190/510 reads (37%) | catalogued as rs767487811, COSV52163284; called by muse, mutect2, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 47/521 reads (9%) | catalogued as COSV64602454; called by pindel, varscan2*
- SERPINH1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 187/449 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.59); catalogued as rs753922805, COSV63997995; called by muse, mutect2, varscan2
- SESN1 | c.961C>T p.P321S (on ENST00000356644 / NM_001199933.1; = p.P380S on NM_014454.3) | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as rs1273995657; called by muse, mutect2, varscan2
- SETX | c.7813C>T p.R2605W | Missense Mutation (SNP) | VAF 133/356 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs1427485242; called by muse, mutect2, varscan2
- SGO1 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99768306; called by muse, mutect2
- SH3BP5L | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); catalogued as rs141743810, COSV100821933; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | catalogued as rs746556543; called by mutect2, varscan2
- SIGLEC1 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 172/558 reads (31%) | catalogued as rs538009435, COSV52463142; called by muse, mutect2, varscan2
- SIN3A | c.3689C>T p.T1230I | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV51252467; called by muse, mutect2, varscan2
- SIX3 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 84/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578552; called by muse, mutect2, varscan2
- SLC1A5 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779397454; called by muse, mutect2, varscan2
- SLC23A3 | c.1529C>T p.T510M (on ENST00000409878 / NM_001144889.2; = p.T393M on NM_144712.5) | Missense Mutation (SNP) | VAF 188/237 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759774447, COSV55407424; called by muse, mutect2, varscan2
- SLC34A3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 134/653 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161944832, COSV63186652; called by muse, mutect2, varscan2
- SLC39A4 | c.1876G>A p.V626M (on ENST00000301305 / NM_001374839.1; = p.V601M on NM_017767.3) | Missense Mutation (SNP) | VAF 258/756 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs888642619; called by muse, varscan2
- SLC6A6 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1014442973; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 35/258 reads (14%) | catalogued as rs753589038, COSV53507811; called by mutect2, varscan2
- SLC9A9 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 139/374 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.107); catalogued as rs767114012, COSV57237555; called by muse, mutect2, varscan2
- SLCO2A1 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 232/581 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs150153024, COSV60484227; called by muse, varscan2
- SLITRK4 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782819249, COSV62023474; called by muse, mutect2, varscan2
- SLTM | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as COSV65850275; called by muse, mutect2, varscan2
- SNAP91 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV52129351; called by muse, mutect2, varscan2
- SNRK | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs766970075, COSV56067305; called by muse, mutect2, varscan2
- SOX1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as rs1465709458; called by muse, mutect2, varscan2
- SP2 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1042801367; called by muse, mutect2, varscan2
- SPATA31A3 | c.257_258del p.E86Vfs*24 | Frame Shift Del (DEL) | VAF 108/666 reads (16%) | catalogued as rs1466605369; called by pindel, varscan2
- SPEG | c.6697dup p.Q2233Pfs*90 | Frame Shift Ins (INS) | VAF 274/396 reads (69%) | catalogued as rs752907815; called by mutect2, varscan2
- SPTBN1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 210/280 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs771485544; called by muse, mutect2, varscan2
- SPTBN1 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 171/471 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs1020175965; called by muse, mutect2, varscan2
- SRPRA | c.1652_1654del p.G551del | In Frame Del (DEL) | VAF 85/235 reads (36%) | catalogued as rs750239164; called by mutect2, pindel, varscan2
- SRRM3 | c.551del p.K184Rfs*23 | Frame Shift Del (DEL) | VAF 62/264 reads (23%) | catalogued as rs1554608587; called by mutect2, pindel, varscan2
- SSR1 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 154/519 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1274733679; called by muse, mutect2, varscan2
- STAG3 | c.3046T>C p.S1016P | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779587903, COSV57933450; called by muse, mutect2, varscan2
- STK33 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs936275480, COSV59397545; called by muse, mutect2, varscan2
- STRC | c.461del p.P154Lfs*30 | Frame Shift Del (DEL) | VAF 236/1422 reads (17%) | catalogued as rs1411667337; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNE1 | c.17896C>T p.Q5966* (on ENST00000367255 / NM_182961.4; = p.Q5895* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 203/833 reads (24%) | catalogued as COSV54982262; called by muse, mutect2, varscan2
- SYNE1 | c.3850C>T p.R1284W (on ENST00000367255 / NM_182961.4; = p.R1291W on NM_033071.3) | Missense Mutation (SNP) | VAF 184/701 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs140780725; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYNM | c.4424G>A p.R1475Q (on ENST00000336292 / NM_145728.3; = p.R1163Q on NM_015286.6) | Missense Mutation (SNP) | VAF 279/730 reads (38%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.506); catalogued as rs370900480; called by muse, mutect2, varscan2
- TBP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 55/342 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs1296555536; called by muse, mutect2, varscan2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 115/457 reads (25%) | catalogued as rs778855667; called by mutect2, pindel, varscan2
- TENM2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 111/524 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.989); catalogued as COSV101595620; called by muse, mutect2, varscan2
- TENM3 | c.7856G>A p.R2619H | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs1214038143, COSV69299013; called by muse, mutect2, varscan2
- TEX2 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs782361810, COSV51978602; called by muse, mutect2, varscan2
- TFAP4 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1271789045, COSV104390907; called by muse, mutect2, varscan2
- TGDS | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54301862; called by muse, mutect2, varscan2
- TJP2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 280/676 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs765794053, COSV55272037; called by muse, mutect2, varscan2
- TJP2 | c.3291G>A p.M1097I | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99601299; called by muse, mutect2, varscan2
- TMEM104 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.552); catalogued as rs749417502, COSV59108324; called by muse, mutect2, varscan2
- TMEM168 | c.929T>A p.I310N | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs760846037; called by muse, varscan2
- TMEM229A | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 214/355 reads (60%) | catalogued as COSV71900363; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 60/196 reads (31%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS15 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as rs778496939, COSV53034807; called by muse, mutect2, varscan2
- TNFRSF11B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375274060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNXB | c.12254C>T p.T4085I (on ENST00000647633; = p.T3838I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 367/1268 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs368428784; called by muse, mutect2, varscan2
- TRBV27 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as rs778182682; called by muse, mutect2, varscan2
- TRIM11 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 170/419 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs767652971; called by muse, mutect2, varscan2
- TRIM58 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769812222; called by muse, mutect2, varscan2
- TRIO | c.6257G>A p.R2086H | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs752936485; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as rs746654944; called by pindel, varscan2
- TRIO | c.7268C>T p.A2423V | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.651); catalogued as rs894555448; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPM2 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 146/418 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs745524892; called by muse, mutect2, varscan2
- TRPM4 | c.380del p.G127Afs*151 | Frame Shift Del (DEL) | VAF 82/342 reads (24%) | catalogued as rs746997172; called by mutect2, pindel, varscan2
- TRPV6 | c.2188C>A p.R730S | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as COSV63891960; called by muse, mutect2, varscan2
- TRRAP | c.9896G>A p.R3299H (on ENST00000359863 / NM_001244580.1; = p.R3270H on NM_003496.3) | Missense Mutation (SNP) | VAF 168/671 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62843412; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 62/158 reads (39%) | catalogued as rs747842861, COSV101181233; called by mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC31 | c.129+1G>A p.X43_splice | Splice Site (SNP) | VAF 314/423 reads (74%) | catalogued as rs776020436; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | catalogued as rs768996038, COSV57882295; called by pindel, varscan2
- TTN | c.57145C>T p.R19049W (on ENST00000591111; = p.R11625W on NM_003319.4) | Missense Mutation (SNP) | VAF 104/141 reads (74%) | PolyPhen probably damaging (0.999); catalogued as rs758801935, COSV60163341; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 96/134 reads (72%) | catalogued as rs760251146; called by mutect2, varscan2
- UGT2B7 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs746024489; called by muse, mutect2, varscan2
- UMODL1 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs779638280; called by muse, mutect2, varscan2
- USH2A | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 186/496 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs193921072, COSV56356434, COSV56419910; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 148/207 reads (71%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP9X | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV61070551; called by muse, mutect2, varscan2
- VANGL2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 212/539 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781038004, COSV63604080; called by muse, mutect2, varscan2
- VGF | c.1533del p.A512Pfs*162 | Frame Shift Del (DEL) | VAF 46/105 reads (44%) | catalogued as COSV50801856; called by mutect2, pindel, varscan2
- VPS8 | c.610G>A p.A204T (on ENST00000625842 / NM_001349294.1; = p.A202T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54987701; called by muse, mutect2, varscan2
- WDR86 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 128/427 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs774752569, COSV57837824; called by muse, mutect2, varscan2
- WFIKKN2 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754056592, COSV100259900; called by muse, mutect2, varscan2
- WWTR1 | c.383del p.P128Rfs*5 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | catalogued as rs1485853361; called by mutect2, varscan2
- XKR3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV58886805; called by muse, mutect2, varscan2
- YEATS2 | c.3030del p.T1011Pfs*25 | Frame Shift Del (DEL) | VAF 99/373 reads (27%) | catalogued as COSV59371815; called by mutect2, pindel, varscan2
- YTHDF1 | c.773del p.G258Vfs*8 | Frame Shift Del (DEL) | VAF 63/393 reads (16%) | catalogued as rs1234547092, COSV64833859; called by mutect2, pindel, varscan2
- YY2 | c.669del p.L224Yfs*18 | Frame Shift Del (DEL) | VAF 121/371 reads (33%) | catalogued as COSV63412713; called by mutect2, pindel, varscan2
- ZAN | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.493); catalogued as rs1401903489; called by muse, mutect2, varscan2
- ZBTB7C | c.960dup p.P321Afs*141 | Frame Shift Ins (INS) | VAF 29/93 reads (31%) | catalogued as rs751294936; called by mutect2, varscan2
- ZC3H13 | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 52/155 reads (34%) | catalogued as COSV54458848; called by muse, mutect2, varscan2
- ZC3H7B | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 144/657 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs758314023; called by muse, mutect2, varscan2
- ZDHHC6 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as rs768612749; called by muse, mutect2, varscan2
- ZFHX4 | c.8000C>T p.A2667V | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs775966431, COSV50478678; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 153/398 reads (38%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF138 | c.562del p.I188Ffs*56 (on ENST00000307355 / NM_001367572.1; = p.I162Ffs*56 on NM_006524.4) | Frame Shift Del (DEL) | VAF 60/294 reads (20%) | catalogued as rs750123890; called by mutect2, pindel, varscan2
- ZNF219 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV53878654; called by muse, mutect2
- ZNF283 | c.370del p.I124Yfs*10 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | catalogued as rs779324028; called by pindel, varscan2
- ZNF366 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775979279, COSV59216828; called by muse, mutect2, varscan2
- ZNF493 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 90/406 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs755594208, COSV62752799; called by muse, mutect2, varscan2
- ZNF536 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs1481304465; called by muse, mutect2, varscan2
- ZNF592 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 186/573 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs746252249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 61/187 reads (33%) | catalogued as rs1264060719; called by mutect2, pindel, varscan2
- ZNF726 | c.1166G>T p.R389M | Missense Mutation (SNP) | VAF 377/701 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV100484630; called by muse, mutect2, varscan2
- ZNF761 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 252/440 reads (57%) | catalogued as rs373350015; called by muse, mutect2, varscan2
- ZNF764 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.418); catalogued as rs1233890286; called by muse, mutect2, varscan2
- ZNF777 | c.1285T>G p.S429A | Missense Mutation (SNP) | VAF 64/458 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1279804296; called by muse, mutect2, varscan2
- ZNF785 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as rs764129454; called by muse, mutect2, varscan2
- ZSWIM5 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs771729124; called by muse, mutect2, varscan2
- A1BG | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 126/417 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ABCC2 | c.53G>C p.S18T | Missense Mutation (SNP) | VAF 176/612 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC8 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 158/463 reads (34%) | called by muse, mutect2, varscan2
- ABCF2 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACOT1 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.089); called by mutect2, varscan2
- ACSM1 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ADAM11 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 157/485 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ADGRA3 | c.2571del p.A858Lfs*22 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, pindel, varscan2
- ADHFE1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 120/311 reads (39%) | called by muse, mutect2, varscan2
- ADRB1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- AEBP2 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 270/319 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHI1 | c.3452A>G p.Q1151R | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, varscan2
- AHNAK2 | c.11533del p.D3845Tfs*16 | Frame Shift Del (DEL) | VAF 281/869 reads (32%) | called by mutect2, pindel, varscan2
- AJUBA | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 154/426 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- AKTIP | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ALG11 | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 215/513 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ALG9 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 147/434 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ALKBH7 | c.361dup p.H121Pfs*48 | Frame Shift Ins (INS) | VAF 62/284 reads (22%) | called by mutect2, pindel, varscan2
- AMPD1 | c.2003dup p.L668Ffs*16 | Frame Shift Ins (INS) | VAF 84/298 reads (28%) | called by mutect2, pindel, varscan2
- ANGPT4 | c.1026dup p.Q343Sfs*23 | Frame Shift Ins (INS) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD52 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 107/427 reads (25%) | called by muse, mutect2, varscan2
- ANKS6 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- ANO4 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 206/869 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APH1A | c.122del p.F41Sfs*19 | Frame Shift Del (DEL) | VAF 52/178 reads (29%) | called by mutect2, pindel, varscan2
- AQP4 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 143/372 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARFGEF2 | c.1983dup p.I662Dfs*15 | Frame Shift Ins (INS) | VAF 90/591 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF12 | c.3923C>A p.S1308Y | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGEF9 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.3145_3146del p.L1049Gfs*55 | Frame Shift Del (DEL) | VAF 114/418 reads (27%) | called by pindel, varscan2
- ARID1A | c.4403del p.P1468Lfs*13 | Frame Shift Del (DEL) | VAF 190/592 reads (32%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 166/505 reads (33%) | called by mutect2, pindel, varscan2
- ARMC5 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 63/538 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ARSI | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARX | c.590del p.G197Afs*128 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- ASAH1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 216/581 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ASB4 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 131/424 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ASTE1 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATG9B | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ATL2 | c.1193T>C p.M398T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP11C | c.767del p.N256Ifs*20 | Frame Shift Del (DEL) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ATP6V1A | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ATP8B4 | c.3440del p.N1147Ifs*35 | Frame Shift Del (DEL) | VAF 114/384 reads (30%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1953dup p.V652Cfs*19 | Frame Shift Ins (INS) | VAF 34/166 reads (20%) | called by mutect2, varscan2
- AXDND1 | c.638+2T>C p.X213_splice | Splice Site (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.1349A>T p.D450V | Missense Mutation (SNP) | VAF 83/310 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- BCKDHB | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 172/654 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL11B | c.898C>T p.R300W (on ENST00000357195 / NM_001282237.2; = p.R229W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- BCL2L12 | c.444dup p.S149Lfs*2 | Frame Shift Ins (INS) | VAF 234/562 reads (42%) | called by mutect2, pindel, varscan2
- BMPR1A | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 136/806 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNIP3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BPIFB4 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 194/782 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BSND | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 49/128 reads (38%) | called by muse, varscan2
- C10orf71 | c.3361G>T p.G1121C | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- C1QL3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 119/467 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- C2CD6 | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 121/156 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf16 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CABIN1 | c.6085C>T p.P2029S | Missense Mutation (SNP) | VAF 254/724 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.1568T>C p.V523A (on ENST00000350061 / NM_001128840.3; = p.V543A on NM_000720.4) | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CACNA1I | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNG8 | c.510C>T p.G170= | Splice Region (SNP) | VAF 281/973 reads (29%) | called by muse, mutect2, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 59/183 reads (32%) | called by mutect2, pindel
- CASK | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CASP8AP2 | c.2861dup p.N954Kfs*5 | Frame Shift Ins (INS) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- CBARP | c.556G>A p.A186T (on ENST00000382477; = p.A166T on NM_152769.3) | Missense Mutation (SNP) | VAF 142/520 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CBLIF | c.973dup p.V325Gfs*2 | Frame Shift Ins (INS) | VAF 322/902 reads (36%) | called by mutect2, varscan2
- CCDC102B | c.108del p.R37Gfs*89 | Frame Shift Del (DEL) | VAF 198/591 reads (34%) | called by mutect2, pindel, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 50/143 reads (35%) | called by mutect2, pindel, varscan2
- CCNL2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCR9 | c.1043G>T p.R348M (on ENST00000357632 / NM_031200.3; = p.R336M on NM_006641.4) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CD300E | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 112/625 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK12 | c.3994C>T p.P1332S (on ENST00000447079 / NM_016507.4; = p.P1323S on NM_015083.3) | Missense Mutation (SNP) | VAF 125/303 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEL | c.661G>A p.A221T (on ENST00000673714; = p.A218T on NM_001807.6) | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 74/206 reads (36%) | called by mutect2, pindel, varscan2
- CEP120 | c.989del p.P330Qfs*14 | Frame Shift Del (DEL) | VAF 52/193 reads (27%) | called by mutect2, pindel, varscan2
- CEP250 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CEP295 | c.5639_5642del p.S1880* | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- CEP295NL | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CFAP43 | c.3413T>C p.M1138T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CFAP46 | c.3481C>T p.L1161F | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFP | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 147/446 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CHCHD2 | c.119del p.P40Hfs*16 | Frame Shift Del (DEL) | VAF 134/614 reads (22%) | called by mutect2, pindel, varscan2
- CHD1 | c.3960dup p.E1321Rfs*17 | Frame Shift Ins (INS) | VAF 59/158 reads (37%) | called by mutect2, varscan2
- CHPF2 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHPF2 | c.1966del p.R656Gfs*5 | Frame Shift Del (DEL) | VAF 51/231 reads (22%) | called by mutect2, pindel, varscan2
- CILP2 | c.2040G>T p.K680N | Missense Mutation (SNP) | VAF 117/215 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CLDND1 | c.403+6T>C | Splice Region (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- CLSPN | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMIP | c.817C>T p.H273Y (on ENST00000537098 / NM_198390.2; = p.H179Y on NM_030629.3) | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- COL22A1 | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL2A1 | c.2804G>A p.S935N | Missense Mutation (SNP) | VAF 474/947 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COLCA2 | c.236del p.P79Qfs*106 | Frame Shift Del (DEL) | VAF 53/290 reads (18%) | called by mutect2, varscan2
- CPNE1 | c.-196-1G>T | Splice Site (SNP) | VAF 57/385 reads (15%) | called by muse, mutect2, varscan2
- CPNE3 | c.820-3del | Splice Region (DEL) | VAF 36/107 reads (34%) | called by mutect2, pindel, varscan2
- CRACDL | c.2639A>C p.K880T | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CSMD3 | c.5875T>C p.Y1959H (on ENST00000297405 / NM_001363185.1; = p.Y1855H on NM_052900.3) | Missense Mutation (SNP) | VAF 158/443 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3064T>C p.Y1022H (on ENST00000297405 / NM_001363185.1; = p.Y918H on NM_052900.3) | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CSTF1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 59/260 reads (23%) | called by muse, mutect2, varscan2
- CTTN | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP26A1 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 298/529 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CYP2B6 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 214/836 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP46A1 | c.591del p.F197Lfs*19 | Frame Shift Del (DEL) | VAF 58/189 reads (31%) | called by mutect2, pindel, varscan2
- CYP4F11 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 126/884 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CYTIP | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPDC1B | c.234del p.K78Nfs*3 | Frame Shift Del (DEL) | VAF 180/515 reads (35%) | called by mutect2, pindel, varscan2
- DERPC | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DEXI | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 130/394 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DLGAP4 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 366/635 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DMRT2 | c.105dup p.G36Rfs*17 | Frame Shift Ins (INS) | VAF 118/381 reads (31%) | called by mutect2, pindel, varscan2
- DNAH12 | c.5231T>C p.L1744P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.469del p.R157Efs*36 | Frame Shift Del (DEL) | VAF 108/325 reads (33%) | called by mutect2, pindel, varscan2
- DNAJC13 | c.727del p.I243Yfs*13 | Frame Shift Del (DEL) | VAF 83/258 reads (32%) | called by mutect2, varscan2
- DOCK4 | c.4855G>A p.V1619M | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOT1L | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 109/374 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPF1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 205/426 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DSE | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DYNC2H1 | c.12521del p.F4174Sfs*28 | Frame Shift Del (DEL) | VAF 97/314 reads (31%) | called by mutect2, pindel, varscan2
- E2F3 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 175/649 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- E2F8 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2S3 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EIF4G1 | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EIF4H | c.537del p.M180Wfs*46 | Frame Shift Del (DEL) | VAF 62/264 reads (23%) | called by mutect2, pindel, varscan2
- ENOX2 | c.1101G>T p.E367D (on ENST00000338144 / NM_001382520.1; = p.E338D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ENTPD4 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 164/406 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- EPHA8 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPN1 | c.1036C>A p.P346T (on ENST00000270460 / NM_001321263.1; = p.P321T on NM_013333.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPSTI1 | c.925A>T p.N309Y (on ENST00000398762 / NM_001330543.2; = p.N298Y on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERVV-2 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ESPN | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 178/461 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ESRP2 | c.1024G>A p.G342R (on ENST00000565858 / NM_001365264.1; = p.G332R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESX1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETAA1 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- F5 | c.585dup p.G196Rfs*5 | Frame Shift Ins (INS) | VAF 122/366 reads (33%) | called by mutect2, pindel, varscan2
- FAAP24 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 149/295 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- FABP2 | c.146_147del p.T49Sfs*11 | Frame Shift Del (DEL) | VAF 46/179 reads (26%) | called by pindel, varscan2
- FAM120C | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 173/476 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- FBLN2 | c.686del p.P229Qfs*45 | Frame Shift Del (DEL) | VAF 81/260 reads (31%) | called by mutect2, pindel, varscan2
- FBXO9 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FCRL2 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 104/294 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 62/294 reads (21%) | called by mutect2, pindel, varscan2
- FERD3L | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FEZF2 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- FGF2 | c.506del p.N169Tfs*50 | Frame Shift Del (DEL) | VAF 90/368 reads (24%) | called by mutect2, pindel, varscan2
- FLG | c.6362A>G p.Q2121R | Missense Mutation (SNP) | VAF 261/702 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- FLNA | c.3652A>G p.T1218A | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FRMD6 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FRMPD3 | c.3028G>T p.G1010W | Missense Mutation (SNP) | VAF 155/392 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- FZD10 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 407/488 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FZD5 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD9 | c.489dup p.A164Rfs*132 | Frame Shift Ins (INS) | VAF 94/464 reads (20%) | called by mutect2, pindel, varscan2
- GABRB2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- GABRR2 | c.261C>G p.S87R | Missense Mutation (SNP) | VAF 125/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGACT | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GIMAP4 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 144/608 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GIMAP7 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 140/612 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- GJA1 | c.450del p.L151Cfs*21 | Frame Shift Del (DEL) | VAF 221/876 reads (25%) | called by mutect2, pindel, varscan2
- GLI1 | c.2798del p.G933Vfs*13 | Frame Shift Del (DEL) | VAF 93/206 reads (45%) | called by mutect2, pindel, varscan2
- GOLGA6L10 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 289/1183 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- GOLIM4 | c.252del p.A85Qfs*10 | Frame Shift Del (DEL) | VAF 62/210 reads (30%) | called by mutect2, pindel, varscan2
- GPNMB | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GRIK4 | c.2084A>G p.Y695C | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GRIN1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.106); called by muse, mutect2
- GRK6 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GTF2I | c.374-1G>T p.X125_splice | Splice Site (SNP) | VAF 94/340 reads (28%) | called by muse, mutect2, varscan2
- GTPBP3 | c.1227G>T p.E409D | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GYS1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 190/363 reads (52%) | called by muse, mutect2, varscan2
- HBP1 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 108/328 reads (33%) | called by muse, mutect2, varscan2
- HERC2 | c.14232G>T p.Q4744H | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGFAC | c.246dup p.L83Afs*13 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- HHEX | c.43dup p.V15Gfs*122 | Frame Shift Ins (INS) | VAF 81/341 reads (24%) | called by mutect2, pindel, varscan2
- HIC1 | c.1107del p.P371Rfs*82 (on ENST00000322941 / NM_001098202.1; = p.P352Rfs*82 on NM_006497.4) | Frame Shift Del (DEL) | VAF 84/237 reads (35%) | called by mutect2, pindel, varscan2
- HLA-F | c.1037-3T>C | Splice Region (SNP) | VAF 70/285 reads (25%) | called by muse, mutect2, varscan2
- HMCN2 | c.13551G>T p.E4517D | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HOXB1 | c.428del p.P143Lfs*41 | Frame Shift Del (DEL) | VAF 88/271 reads (32%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- HPSE2 | c.1436G>T p.R479M | Missense Mutation (SNP) | VAF 196/803 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSPB6 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSPG2 | c.3769C>A p.P1257T | Missense Mutation (SNP) | VAF 198/584 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HUWE1 | c.2965del p.R989Dfs*21 | Frame Shift Del (DEL) | VAF 111/366 reads (30%) | called by pindel, varscan2
- IDUA | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- IFIT1 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IHH | c.797del p.P266Hfs*99 | Frame Shift Del (DEL) | VAF 485/824 reads (59%) | called by mutect2, pindel, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, varscan2
- IL4R | c.1793del p.P598Qfs*89 | Frame Shift Del (DEL) | VAF 50/141 reads (35%) | called by mutect2, pindel, varscan2
- ILDR2 | c.1397G>A p.S466N | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- INA | c.1495del p.I499Yfs*15 | Frame Shift Del (DEL) | VAF 29/141 reads (21%) | called by pindel, varscan2
- IQSEC2 | c.66C>G p.Y22* | Nonsense Mutation (SNP) | VAF 281/724 reads (39%) | called by muse, mutect2, varscan2
- IRS2 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IRX3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITGA9 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 279/789 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 81/226 reads (36%) | called by mutect2, varscan2
- JARID2 | c.2541+1G>T p.X847_splice | Splice Site (SNP) | VAF 92/301 reads (31%) | called by muse, mutect2, varscan2
- JMJD1C | c.6512A>G p.K2171R | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JMJD1C | c.6101del p.N2034Tfs*37 | Frame Shift Del (DEL) | VAF 251/525 reads (48%) | called by mutect2, pindel, varscan2
- JRKL | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 82/198 reads (41%) | called by muse, mutect2, varscan2
- KALRN | c.8367G>T p.E2789D (on ENST00000360013 / NM_001024660.4; = p.E1092D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KANK4 | c.2005A>G p.N669D | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD6 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 190/559 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNH1 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 112/292 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- KCNK16 | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- KCNQ4 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- KCTD2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- KDM1B | c.1226C>T p.T409I (on ENST00000449850; = p.T277I on NM_153042.4) | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KDM4A | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- KDM4C | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KIAA0100 | c.6481G>A p.A2161T | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF2A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLC1 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- KLF14 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC7B | c.879G>T p.Q293H (on ENST00000395676; = p.Q934H on NM_138433.5) | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- KLHL17 | c.419del p.P140Lfs*35 | Frame Shift Del (DEL) | VAF 256/791 reads (32%) | called by mutect2, pindel, varscan2
- KLHL31 | c.693A>G p.I231M | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 83/358 reads (23%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 106/379 reads (28%) | called by mutect2, varscan2
- KRI1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 125/452 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRI1 | c.1691A>G p.Q564R | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KRTAP10-8 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 203/555 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- KSR1 | c.64del p.D22Mfs*71 | Frame Shift Del (DEL) | VAF 58/278 reads (21%) | called by mutect2, pindel
- LAMB1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 99/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- LCE1E | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 161/495 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- LECT2 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 131/301 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- LETM2 | c.376del p.I126Sfs*5 (on ENST00000379957 / NM_001286819.2; = p.I79Sfs*5 on NM_144652.3) | Frame Shift Del (DEL) | VAF 129/446 reads (29%) | called by mutect2, pindel, varscan2
- LRP5 | c.3320T>C p.F1107S | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- LSAMP | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- LTK | c.1265del p.P422Qfs*6 | Frame Shift Del (DEL) | VAF 72/226 reads (32%) | called by mutect2, pindel
- MAG | c.803del p.P268Rfs*4 | Frame Shift Del (DEL) | VAF 108/190 reads (57%) | called by mutect2, varscan2
- MAMSTR | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 229/414 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN2A1 | c.2623A>G p.N875D | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MANBA | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 191/547 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAPK6 | c.1245del p.F415Lfs*40 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCO | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 85/194 reads (44%) | called by muse, mutect2, varscan2
- MARK1 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MARK4 | c.422-2A>T p.X141_splice | Splice Site (SNP) | VAF 289/518 reads (56%) | called by muse, mutect2, varscan2
- MBOAT7 | c.1155del p.R386Gfs*2 | Frame Shift Del (DEL) | VAF 79/341 reads (23%) | called by mutect2, pindel, varscan2
- MED13L | c.3169C>A p.P1057T | Missense Mutation (SNP) | VAF 351/426 reads (82%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEGF8 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MEPE | c.694del p.I232Sfs*45 | Frame Shift Del (DEL) | VAF 56/126 reads (44%) | called by mutect2, varscan2
- MERTK | c.1288G>T p.G430W | Missense Mutation (SNP) | VAF 291/375 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MEX3A | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 183/494 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFSD12 | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 180/308 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MGAT1 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 52/178 reads (29%) | PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MICAL1 | c.2610dup p.E871Rfs*7 | Frame Shift Ins (INS) | VAF 94/432 reads (22%) | called by mutect2, pindel, varscan2
- MLIP | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MMEL1 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMP10 | c.88A>G p.N30D | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MMP24 | c.508T>G p.Y170D | Missense Mutation (SNP) | VAF 130/419 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MPPE1 | c.679-4G>A | Splice Region (SNP) | VAF 78/252 reads (31%) | called by muse, mutect2, varscan2
- MROH1 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 223/494 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MRPL2 | c.873del p.M292* | Frame Shift Del (DEL) | VAF 32/265 reads (12%) | called by mutect2, pindel
- MRPS11 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTNR1A | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 167/459 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 143/421 reads (34%) | SIFT tolerated (0.24); called by muse, mutect2, varscan2
- MYC | c.743C>G p.T248S (on ENST00000377970; = p.T263S on NM_002467.6) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYH13 | c.1443C>A p.N481K | Missense Mutation (SNP) | VAF 289/774 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYLIP | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYO15A | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MYO15A | c.4303T>C p.Y1435H | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYO1H | c.2314A>G p.S772G | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- N4BP2L2 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 123/379 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
721 further variants in this file (234 protein-altering or splice-affecting, 287 silent, 200 other) are not listed here.
